Somatic mutation profile of tumor specimen TARGET-30-PAIFXV-01A (aliquot TARGET-30-PAIFXV-01A-01D) from TARGET case TARGET-30-PAIFXV, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 5.5 years (2,004 days).
Specimen TARGET-30-PAIFXV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 186304c8-1553-42d9-84fe-e2c9dd460e07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAIFXV-10A (Blood Derived Normal), aliquot TARGET-30-PAIFXV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8206f31f-1df6-40e3-9770-c66403cc85f4

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Frame Shift Del 1, Intron 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.7435G>C p.E2479Q | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57211919; called by muse, mutect2, varscan2
- AKAP6 | c.2081G>T p.G694V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1473045759, COSV55212183; called by muse, mutect2, varscan2
- BTNL3 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.357); catalogued as COSV61564823; called by mutect2, varscan2
- CFAP299 | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.384); catalogued as COSV63876915; called by muse, mutect2, varscan2
- DISP3 | c.2209G>C p.V737L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV53821410, COSV53826191; called by muse, mutect2, varscan2
- ENAM | c.3263C>T p.T1088M | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs139404568; called by mutect2, varscan2
- FHOD3 | c.3890A>C p.Q1297P (on ENST00000359247 / NM_001281739.3; = p.Q1314P on NM_025135.5) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.374); catalogued as COSV57171991; called by muse, mutect2, varscan2
- HSPA2 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as COSV55969436; called by muse, mutect2
- ITGA6 | c.2433G>C p.K811N (on ENST00000442250; = p.K772N on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1021042255, COSV51223524; called by muse, mutect2, varscan2
- MXRA5 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54233139; called by muse, mutect2
- NTNG1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV53969555, COSV99640074; called by mutect2, varscan2
- NUP88 | c.1451C>A p.T484N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs745584195, COSV56704995; called by mutect2, varscan2
- PLD1 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV60567540, COSV60568273; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.942C>A p.S314R | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV57964587; called by muse, mutect2, varscan2
- SLC28A2 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.122); catalogued as COSV100754561, COSV61663867; called by muse, mutect2, varscan2
- SYNE2 | c.15973G>C p.D5325H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59948932; called by muse, mutect2, varscan2
- TAS1R2 | c.1670T>C p.V557A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64744689; called by muse, mutect2, varscan2
- CPAMD8 | c.1236+1del p.X412_splice (on ENST00000651564; = p.X365_splice on NM_015692.5) | Splice Site (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- OR14K1 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SLC1A3 | c.1198G>C p.D400H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SPTB | c.5312G>A p.W1771* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | called by mutect2, varscan2
- SYDE2 | c.1526del p.G509Afs*12 | Frame Shift Del (DEL) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- CELSR2 | c.3900C>T p.H1300= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1294486832, COSV54770676; called by mutect2, varscan2
- KIF26B | c.2271C>T p.L757= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs370466424; called by mutect2, varscan2
- NCOA2 | c.378C>T p.F126= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV104440448, COSV71763892; called by muse, mutect2, varscan2
- PCDHGA2 | c.879G>A p.E293= | Silent (SNP) | VAF 50/165 reads (30%) | catalogued as rs1418882413, COSV53937196; called by muse, mutect2, varscan2
- PGBD2 | c.1527C>A p.A509= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV61400084; called by mutect2, varscan2
- SRRM2 | c.405C>T p.L135= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs372723122, COSV57069987, COSV57072484; called by muse, mutect2, varscan2
- HNF4G | c.-23-3802A>T | Intron (SNP) | VAF 10/95 reads (11%) | called by mutect2, varscan2
